Gene-level copy-number profile of tumor specimen TCGA-CV-7102-01A from TCGA case TCGA-CV-7102, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 76.1 years (27,805 days).
Specimen TCGA-CV-7102-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.dce23048-cc8d-4df4-988c-cb55a0e6ee8d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7102-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df274d2f-8c7f-43d1-bd5a-a3f174851c3c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 731; copy number 2: 11,929; copy number 3: 22,799; copy number 4: 22,537; copy number 5: 479; copy number 6: 751; copy number 7: 260; copy number 8: 46; copy number 9: 39; copy number 10: 11; copy number 20: 28; copy number 21: 33; copy number 28: 36; copy number 32: 27; copy number 45: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7102-01A-11D-2010-01): tumor purity 0.47, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,648,411–121,580,524, 49 genes (within-gene range 0–2): PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr9:21,967,752–23,438,700, 13 genes (within-gene range 0–4): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr12:78,052,181–78,131,004, 2 genes: AC073571.1, PRXL2AP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 523 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:136,784,045–139,043,302, 44 genes, copy number 7–10: AL121933.2, PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1, OLIG3, BTF3L4P3, AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL.
- chr7:54,185,071–56,484,386, 71 genes, copy number 20–45 (broad region; genes not listed).
- chr8:120,761,253–128,187,101, 130 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:131,712,512–140,458,579, 83 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr9:13,927,971–13,987,909, 2 genes, copy number 8: LINC00583, PES1P2.
- chr11:68,683,779–72,573,229, 133 genes, copy number 7–32 (broad region; genes not listed).
- chr12:125,065,434–126,434,227, 20 genes, copy number 7 (within-gene range 2–7): AACS, AC122688.3, AC122688.2, AC122688.5, AC122688.4, TMEM132B, AC093028.1, AC005252.2, AC005252.4, AC005252.3, AC005252.1, LINC00939, LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825.
- chr14:20,734,578–21,206,900, 36 genes, copy number 28: EDDM3DP, EDDM3A, EDDM3B, RNASE6, AL133371.2, RNASE1, AL133371.3, AL133371.1, RNASE3, AL355922.4, AL355922.3, AL355922.1, RNASE2, RN7SL189P, AL355922.2, METTL17, AL161668.3, SLC39A2, NDRG2, MIR6717, TPPP2, AL161668.4, AL161668.2, RNASE13, RNASE7, RNASE8, ARHGEF40, ZNF219, TMEM253, AL161668.1, CKAP2P1, RNU6-252P, OR5AU1, SMARCE1P3, AL157687.1, LINC00641.
- chr16:78,495,926–78,553,296, 4 genes, copy number 7: AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Autosomal genes at a single copy (total copy number 1): 731. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
